Somatic mutation profile of tumor specimen TARGET-20-PARWXU-40A (aliquot TARGET-20-PARWXU-40A-01D) from TARGET case TARGET-20-PARWXU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (557 days).
Specimen TARGET-20-PARWXU-40A: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80765148-c83b-4de6-9bf5-ee7237899d0a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARWXU-10A (Blood Derived Normal), aliquot TARGET-20-PARWXU-10A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d2f7e1d-f180-463b-aa2c-6e45dac2e3a2

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/198 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2
- TET2 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54433469; called by muse, mutect2, varscan2
- FAT1 | c.12006G>A p.S4002= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as rs780198819, COSV71676078; called by muse, mutect2, varscan2
